Somatic mutation profile of tumor specimen C3N-02143-03 (aliquot CPT0213230006) from CPTAC case C3N-02143, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G2.
Specimen C3N-02143-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85355350-59e8-42ff-b33f-65402a0064e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02143-71 (Blood Derived Normal), aliquot CPT0213330002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04bcf52b-685e-448a-8d16-fca9a0160a74

The open-access MAF lists 235 somatic variants for this specimen: 155 protein-altering or splice-affecting, 53 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 53, Nonsense Mutation 13, Intron 13, RNA 6, 3'UTR 3, 5'UTR 3, Splice Region 3, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2257del p.L747_P753delinsS | In Frame Del (DEL) | VAF 1302/1834 reads (71%) | hotspot (GDC flag); catalogued as rs121913438, COSV51767961; ClinVar: drug response; called by mutect2, varscan2
- RB1 | c.1389+2T>C p.X463_splice | Splice Site (SNP) | VAF 40/242 reads (17%) | hotspot (GDC flag); catalogued as CS023834, COSV57314766; called by muse, mutect2, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 79/190 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ABHD17A | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 20/598 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV51750858; called by muse, mutect2
- AHNAK2 | c.10721C>A p.P3574H | Missense Mutation (SNP) | VAF 99/621 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60930635; called by muse, mutect2, varscan2
- APBA2 | c.351C>A p.N117K | Missense Mutation (SNP) | VAF 79/475 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); catalogued as COSV68790870; called by muse, mutect2, varscan2
- ARAP3 | c.2767G>A p.V923M | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290242664; called by muse, mutect2
- C1QTNF3 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 122/226 reads (54%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV51470150, COSV99180694; called by muse, mutect2
- CACNA1A | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 74/904 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100801176; called by muse, mutect2
- CCN5 | c.353G>C p.S118T | Missense Mutation (SNP) | VAF 16/544 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99509261; called by muse, mutect2
- CNTN2 | c.2868C>A p.H956Q | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs750428768; called by muse, mutect2, varscan2
- CNTN6 | c.182G>T p.R61M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100611155, COSV63183826; called by muse, mutect2
- COL11A1 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV62181583; called by muse, mutect2, varscan2
- COL1A1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 22/491 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV56802454; called by muse, mutect2
- COL22A1 | c.2594G>T p.G865V | Missense Mutation (SNP) | VAF 42/444 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57344323; called by muse, mutect2
- CYBA | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 82/509 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs755779683; called by muse, mutect2, varscan2
- DNAH6 | c.12020G>A p.R4007Q | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367739383; called by muse, mutect2, varscan2
- DSC2 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.05); catalogued as rs1226238061; called by muse, mutect2, varscan2
- DSCAML1 | c.2407C>T p.R803C (on ENST00000321322; = p.R743C on NM_020693.4) | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58395785; called by muse, mutect2, varscan2
- EGFR | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 98/2540 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753319070; called by muse, mutect2
- FAT2 | c.5163G>T p.E1721D | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1561855680; called by muse, mutect2
- FLNA | c.7778G>A p.G2593E (on ENST00000369850 / NM_001110556.2; = p.G2585E on NM_001456.3) | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM124981, COSV61053035; called by muse, mutect2
- GALR1 | c.382G>C p.A128P | Missense Mutation (SNP) | VAF 71/478 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55319414; called by muse, mutect2, varscan2
- GLB1L2 | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs761945171, COSV56997010; called by muse, mutect2, varscan2
- LAMC3 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 77/748 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778138736; called by muse, mutect2
- LIG4 | c.1835C>G p.S612C | Missense Mutation (SNP) | VAF 25/564 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.469); catalogued as rs932632331; called by muse, mutect2
- LRP1B | c.13096G>T p.G4366W | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67185531, COSV67210927; called by muse, mutect2, varscan2
- LRRK1 | c.1588C>G p.Q530E | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV52620529; called by muse, mutect2
- MACF1 | c.3602G>T p.R1201L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV58377760; called by muse, mutect2
- MERTK | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 49/373 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV54932706; called by muse, mutect2, varscan2
- MIP | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 76/600 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as CM1210382; called by muse, mutect2, varscan2
- MYH1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769113864, COSV56843736; called by muse, mutect2
- MYH13 | c.3137A>C p.K1046T | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1359077021; called by muse, mutect2
- NBEAL1 | c.5748C>G p.F1916L | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs377637308; called by muse, mutect2
- NLRP9 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 8/236 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.065); catalogued as COSV60467059; called by muse, mutect2
- OPCML | c.815T>C p.I272T | Missense Mutation (SNP) | VAF 15/398 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV59417985; called by muse, mutect2
- OR2M7 | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV58740022; called by muse, mutect2
- OR3A3 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 218/583 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.155); catalogued as rs752788944; called by muse, varscan2
- OR8H2 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as COSV57947942; called by muse, mutect2
- PCDHGB2 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV53971022, COSV54018191; called by muse, mutect2
- PDHA2 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 21/223 reads (9%) | catalogued as COSV54778797; called by muse, mutect2
- PLEKHH2 | c.4391C>G p.S1464* | Nonsense Mutation (SNP) | VAF 17/314 reads (5%) | catalogued as rs766682241; called by muse, mutect2
- PPP1R32 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 36/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419828723; called by muse, mutect2
- PRPF8 | c.6919G>A p.E2307K | Missense Mutation (SNP) | VAF 21/533 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as rs1225225736; called by muse, mutect2
- RB1 | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 8/144 reads (6%) | catalogued as CM040261; called by muse, mutect2
- RBM19 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV55692203; called by muse, mutect2
- RHAG | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 29/367 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as rs1222205878; called by muse, mutect2
- RPRD2 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 37/211 reads (18%) | catalogued as rs1404536715; called by muse, mutect2, varscan2
- SFXN1 | c.442G>T p.G148* | Nonsense Mutation (SNP) | VAF 18/266 reads (7%) | catalogued as COSV58494563; called by muse, mutect2
- SPTAN1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 21/629 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV63987721; called by muse, mutect2
- SYT4 | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.439); catalogued as rs1329783966; called by muse, mutect2
- TCTE3 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 9/261 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.242); catalogued as COSV100824882, COSV64650788; called by muse, mutect2
- TENM2 | c.3061C>T p.L1021F (on ENST00000518659 / NM_001122679.2; = p.L789F on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs952713229; called by muse, mutect2
- TNFRSF4 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 47/414 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55419812; called by muse, mutect2, varscan2
- VN1R4 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 15/130 reads (12%) | catalogued as rs771582787, COSV60805234; called by muse, mutect2, varscan2
- XIRP2 | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV54736805; called by muse, mutect2
- ZNF716 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 20/630 reads (3%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.023); catalogued as COSV70783198; called by muse, mutect2
- ZNF716 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 131/414 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV70778848; called by muse, mutect2, varscan2
- AC090517.4 | c.1504A>C p.K502Q | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- AC100868.1 | c.559T>A p.C187S | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- ACP3 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2
- AMPD1 | c.1876T>A p.S626T | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ARGLU1 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 25/642 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); called by muse, mutect2
- ATF6 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 60/355 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CABIN1 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 38/457 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- CHST5 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 65/448 reads (15%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CLOCK | c.1872A>C p.Q624H | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.547); called by muse, mutect2
- CNTN5 | c.1394G>T p.G465V | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- COG7 | c.2146+1G>C p.X716_splice | Splice Site (SNP) | VAF 18/538 reads (3%) | called by muse, mutect2
- CPLX1 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP20A1 | c.1372G>A p.V458I | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- DCHS1 | c.5981G>C p.G1994A | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX10 | c.86A>G p.H29R | Missense Mutation (SNP) | VAF 33/206 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.12614-1G>C p.X4205_splice (on ENST00000409039; = p.X4144_splice on NM_207437.3) | Splice Site (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- DOCK10 | c.1298G>T p.R433I | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- DPEP3 | c.417C>T p.F139= | Splice Region (SNP) | VAF 44/164 reads (27%) | called by muse, mutect2, varscan2
- DPYS | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 18/597 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- DSP | c.1931G>T p.G644V | Missense Mutation (SNP) | VAF 63/417 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DUSP7 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 108/388 reads (28%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.657); called by mutect2, varscan2
- ECSIT | c.945G>A p.R315= | Splice Region (SNP) | VAF 48/345 reads (14%) | called by muse, mutect2, varscan2
- EIF3H | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- ENTPD5 | c.179C>G p.T60S | Missense Mutation (SNP) | VAF 26/293 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); called by muse, mutect2
- FAM131B | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- FAM83B | c.434A>T p.E145V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by mutect2, varscan2
- FLNA | c.7780G>A p.V2594I (on ENST00000369850 / NM_001110556.2; = p.V2586I on NM_001456.3) | Missense Mutation (SNP) | VAF 82/334 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.945); called by muse, mutect2
- FOLH1B | n.805A>T | Splice Region (SNP) | VAF 19/228 reads (8%) | called by muse, mutect2
- FOXB2 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FOXO1 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 66/270 reads (24%) | called by muse, mutect2, varscan2
- FZD10 | c.1264del p.H422Tfs*5 | Frame Shift Del (DEL) | VAF 44/308 reads (14%) | called by mutect2, pindel, varscan2
- GJD2 | c.341del p.L114Qfs*11 | Frame Shift Del (DEL) | VAF 64/454 reads (14%) | called by mutect2, pindel, varscan2
- GLDC | c.2505A>T p.L835F | Missense Mutation (SNP) | VAF 149/657 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GNA13 | c.175A>T p.S59C | Missense Mutation (SNP) | VAF 97/749 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNL2 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- HCN4 | c.174dup p.S59Lfs*66 | Frame Shift Ins (INS) | VAF 28/197 reads (14%) | called by pindel, varscan2
- ITGA3 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 47/564 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITPR2 | c.1691A>T p.Q564L | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KRTAP10-6 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 78/1066 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- LAMC2 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- LEF1 | c.568G>C p.A190P | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- LIG4 | c.2302G>C p.D768H | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2
- LILRB5 | c.149A>T p.Q50L | Missense Mutation (SNP) | VAF 60/433 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MAP4K2 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.026); called by muse, mutect2
- MATK | c.154C>A p.Q52K (on ENST00000310132 / NM_139355.3; = p.Q53K on NM_002378.4) | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2
- MEGF10 | c.1186T>A p.C396S | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMUT | c.562A>G p.M188V | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRC2 | c.3231C>A p.S1077R | Missense Mutation (SNP) | VAF 15/315 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.325); called by muse, mutect2
- MUC2 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- MYLK3 | c.1939C>G p.Q647E | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.18); called by muse, mutect2
- MYT1L | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 97/280 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEFM | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- NHLRC2 | c.1693A>G p.M565V | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- NLRC4 | c.1463G>C p.S488T | Missense Mutation (SNP) | VAF 45/298 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NRXN3 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 26/465 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NSFL1C | c.379A>T p.K127* | Nonsense Mutation (SNP) | VAF 102/391 reads (26%) | called by muse, mutect2, varscan2
- OR1B1 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2G3 | c.746T>C p.I249T | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR52E6 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- OR7C1 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- PAPPA2 | c.5338T>G p.C1780G | Missense Mutation (SNP) | VAF 41/472 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKHD1 | c.7090A>T p.I2364F | Missense Mutation (SNP) | VAF 40/518 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2
- PPP2R2B | c.116T>A p.L39Q (on ENST00000394409; = p.L105Q on NM_181674.2) | Missense Mutation (SNP) | VAF 30/379 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RASAL3 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- RBL2 | c.2632C>T p.Q878* | Nonsense Mutation (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- RPH3A | c.1051C>A p.H351N (on ENST00000389385 / NM_001143854.2; = p.H347N on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RPS6KA6 | c.1792G>T p.G598* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- RTL5 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); called by muse, mutect2
- RYR1 | c.2035A>G p.T679A | Missense Mutation (SNP) | VAF 46/485 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); called by muse, mutect2
- RYR2 | c.1538dup p.H513Qfs*4 | Frame Shift Ins (INS) | VAF 42/156 reads (27%) | called by mutect2, pindel, varscan2
- RYR2 | c.8636C>A p.A2879D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SEC14L6 | c.798G>C p.K266N | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2
- SERPINI1 | c.521C>A p.A174D | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SERTAD1 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SFMBT2 | c.2609A>T p.K870M | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHOC1 | c.1738A>T p.S580C | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.208); called by muse, mutect2
- SHROOM4 | c.1784A>T p.E595V | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SIRPA | c.523T>A p.F175I | Missense Mutation (SNP) | VAF 179/480 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SPHKAP | c.2509G>T p.G837* | Nonsense Mutation (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- SYNE1 | c.14125G>C p.A4709P (on ENST00000367255 / NM_182961.4; = p.A4638P on NM_033071.3) | Missense Mutation (SNP) | VAF 53/435 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- TEX13C | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.477); called by muse, mutect2
- TEX13C | c.734C>A p.S245* | Nonsense Mutation (SNP) | VAF 73/220 reads (33%) | called by muse, mutect2, varscan2
- TEX13C | c.2861C>A p.S954Y | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TRAPPC8 | c.2668G>C p.E890Q | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2
- TRIM28 | c.2275C>T p.Q759* | Nonsense Mutation (SNP) | VAF 24/346 reads (7%) | called by muse, mutect2
- TRIM64 | c.154T>C p.C52R | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UGT2B11 | c.182C>G p.S61C | Missense Mutation (SNP) | VAF 17/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- WDR25 | c.1553G>T p.C518F | Missense Mutation (SNP) | VAF 87/389 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XKR4 | c.501T>A p.F167L | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- ZNF311 | c.801A>C p.Q267H | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ZNF439 | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF572 | c.455G>T p.R152M | Missense Mutation (SNP) | VAF 59/339 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF75A | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF98 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); called by mutect2, varscan2
- ZNF99 | c.2142del p.F714Lfs*12 | Frame Shift Del (DEL) | VAF 61/523 reads (12%) | called by mutect2, varscan2
- ZSCAN16 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.057); called by muse, mutect2
- ADSS2 | c.1344C>T p.S448= | Silent (SNP) | VAF 21/236 reads (9%) | catalogued as rs1375780827; called by muse, mutect2
- AGPAT4 | c.477G>A p.L159= | Silent (SNP) | VAF 30/542 reads (6%) | called by muse, mutect2
- ANKRD7 | c.645G>T p.V215= | Silent (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2
- ATP2B3 | c.423G>A p.S141= | Silent (SNP) | VAF 14/251 reads (6%) | catalogued as rs782291889; called by muse, mutect2
- C1QTNF6 | c.744C>G p.L248= | Silent (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2
- CA9 | c.1251C>A p.A417= | Silent (SNP) | VAF 10/289 reads (3%) | called by muse, mutect2
- CAMSAP1 | c.1650G>T p.V550= | Silent (SNP) | VAF 39/385 reads (10%) | called by muse, mutect2, varscan2
- CASKIN2 | c.867C>G p.L289= | Silent (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- CDH5 | c.2244C>T p.T748= | Silent (SNP) | VAF 73/582 reads (13%) | catalogued as rs750727557, COSV58519394, COSV58520133; called by muse, mutect2, varscan2
- CIT | c.5838C>T p.G1946= | Silent (SNP) | VAF 54/444 reads (12%) | called by muse, mutect2, varscan2
- CPED1 | c.850T>C p.L284= | Silent (SNP) | VAF 15/291 reads (5%) | called by muse, mutect2
- CROCC2 | c.2908C>A p.R970= | Silent (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- DDIT4L | c.579C>T p.S193= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV99913895; called by muse, mutect2, varscan2
- EGFR | c.249G>A p.Q83= | Silent (SNP) | VAF 100/2531 reads (4%) | catalogued as rs939737982; called by muse, mutect2
- FAM120C | c.2220G>T p.R740= | Silent (SNP) | VAF 59/267 reads (22%) | called by muse, mutect2, varscan2
- FAM237A | c.15G>C p.G5= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- FLNA | c.7419G>A p.K2473= (on ENST00000369850 / NM_001110556.2; = p.K2465= on NM_001456.3) | Silent (SNP) | VAF 52/441 reads (12%) | called by mutect2, varscan2
- FN3K | c.87A>T p.R29= | Silent (SNP) | VAF 54/576 reads (9%) | called by muse, mutect2
- GLRA2 | c.1240C>A p.R414= | Silent (SNP) | VAF 136/332 reads (41%) | called by muse, mutect2, varscan2
- HBG2 | c.333G>T p.L111= | Silent (SNP) | VAF 62/564 reads (11%) | called by muse, varscan2
- IGHV3-73 | c.117C>G p.L39= | Silent (SNP) | VAF 49/395 reads (12%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.198C>A p.P66= | Silent (SNP) | VAF 39/189 reads (21%) | catalogued as COSV101188262; called by muse, mutect2, varscan2
- KCNT1 | c.1900C>T p.L634= (on ENST00000488444; = p.L653= on NM_020822.3) | Silent (SNP) | VAF 16/144 reads (11%) | called by muse, mutect2, varscan2
- KLHL1 | c.387G>C p.V129= | Silent (SNP) | VAF 52/416 reads (13%) | catalogued as COSV100918105; called by muse, mutect2, varscan2
- MATK | c.153C>A p.T51= (on ENST00000310132 / NM_139355.3; = p.T52= on NM_002378.4) | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs752496411; called by muse, mutect2, varscan2
- MBD3L2B | c.603G>T p.R201= | Silent (SNP) | VAF 66/443 reads (15%) | called by muse, mutect2, varscan2
- NBAS | c.3216A>G p.A1072= | Silent (SNP) | VAF 23/310 reads (7%) | called by muse, mutect2
- NPY2R | c.306G>T p.L102= | Silent (SNP) | VAF 49/192 reads (26%) | catalogued as COSV100279649; called by muse, mutect2, varscan2
- OMP | c.282C>T p.L94= | Silent (SNP) | VAF 74/655 reads (11%) | called by muse, mutect2, varscan2
- PCDH9 | c.2310A>T p.V770= | Silent (SNP) | VAF 34/258 reads (13%) | catalogued as rs1303942022; called by muse, mutect2, varscan2
- PCDHGA3 | c.489C>A p.G163= | Silent (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- PDSS1 | c.279C>A p.T93= | Silent (SNP) | VAF 95/322 reads (30%) | called by muse, mutect2, varscan2
- PRRT4 | c.2607G>A p.L869= | Silent (SNP) | VAF 81/506 reads (16%) | catalogued as rs1177449612; called by muse, mutect2, varscan2
- PSG2 | c.831G>C p.G277= | Silent (SNP) | VAF 109/493 reads (22%) | catalogued as COSV61546528; called by muse, mutect2, varscan2
- PTPN1 | c.42G>T p.G14= | Silent (SNP) | VAF 18/242 reads (7%) | called by muse, mutect2
- ROBO4 | c.1389T>A p.A463= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as rs1157278964; called by muse, mutect2
- RPS24 | c.171A>G p.V57= | Silent (SNP) | VAF 25/527 reads (5%) | catalogued as rs1306428472; called by muse, mutect2
- SCN8A | c.4341C>T p.F1447= | Silent (SNP) | VAF 13/394 reads (3%) | catalogued as rs1298845619; called by muse, mutect2
- SCNN1G | c.696A>C p.L232= | Silent (SNP) | VAF 80/446 reads (18%) | called by muse, mutect2, varscan2
- SDHA | c.1372T>C p.L458= | Silent (SNP) | VAF 73/676 reads (11%) | called by muse, mutect2, varscan2
- SLC24A4 | c.276T>C p.N92= | Silent (SNP) | VAF 30/406 reads (7%) | called by muse, mutect2
- SLC35B4 | c.954G>A p.G318= | Silent (SNP) | VAF 11/252 reads (4%) | called by muse, mutect2
- STAB2 | c.1233A>C p.T411= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- TBC1D32 | c.3613C>T p.L1205= | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as rs1450242866; called by muse, mutect2, varscan2
- TM2D2 | c.117C>T p.T39= | Silent (SNP) | VAF 40/320 reads (13%) | catalogued as rs771822122; called by muse, mutect2, varscan2
- TMCC1 | c.972C>T p.D324= | Silent (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
- TMPRSS11A | c.585T>A p.I195= | Silent (SNP) | VAF 33/251 reads (13%) | called by muse, mutect2, varscan2
- TRAM1L1 | c.864T>G p.T288= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- XKR7 | c.1185C>T p.N395= | Silent (SNP) | VAF 14/230 reads (6%) | catalogued as rs372168274; called by muse, mutect2
- ZNF155 | c.39G>T p.V13= | Silent (SNP) | VAF 13/334 reads (4%) | called by muse, mutect2
- ZNF358 | c.1248C>T p.A416= | Silent (SNP) | VAF 21/180 reads (12%) | catalogued as rs1246733147; called by muse, mutect2, varscan2
- ZNF648 | c.825C>A p.A275= | Silent (SNP) | VAF 45/260 reads (17%) | catalogued as rs1271508766; called by muse, mutect2, varscan2
- ZNF660 | c.441G>A p.S147= | Silent (SNP) | VAF 63/211 reads (30%) | catalogued as rs1217026213; called by muse, mutect2, varscan2
- AC106741.1 | c.*27T>A | 3'UTR (SNP) | VAF 41/301 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.2156+20G>A | Intron (SNP) | VAF 32/601 reads (5%) | catalogued as rs374365078; called by muse, mutect2
- BAALC-AS2 | n.215T>A | RNA (SNP) | VAF 100/642 reads (16%) | called by muse, mutect2, varscan2
- CARS1 | c.26-5546G>A | Intron (SNP) | VAF 24/156 reads (15%) | catalogued as rs774269143; called by muse, mutect2
- CCL4L2 | c.191+180G>T | Intron (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- CLEC6A | c.-15C>T | 5'UTR (SNP) | VAF 23/243 reads (9%) | called by muse, mutect2
- COG5 | c.1686+1523T>C | Intron (SNP) | VAF 23/293 reads (8%) | called by muse, mutect2
- CXCR2P1 | n.1026T>C | RNA (SNP) | VAF 19/247 reads (8%) | catalogued as rs776665994; called by muse, mutect2
- DCUN1D4 | c.26-2875G>A | Intron (SNP) | VAF 52/204 reads (25%) | called by muse, mutect2, varscan2
- DNAH1 | c.-2G>T | 5'UTR (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.1186G>A | RNA (SNP) | VAF 8/181 reads (4%) | called by muse, mutect2
- ITGA7 | chr12:55712248 G>A | 5'Flank (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- LAMA1 | c.233-12T>A | Intron (SNP) | VAF 16/490 reads (3%) | called by muse, mutect2
- LINC00905 | n.1078C>A | RNA (SNP) | VAF 58/380 reads (15%) | called by mutect2, varscan2
- MKKS | c.-19A>G | 5'UTR (SNP) | VAF 52/171 reads (30%) | called by muse, mutect2, varscan2
- NEK8 | c.487-46G>C | Intron (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- NOXO1 | chr16:1984173 G>A | 5'Flank (SNP) | VAF 23/169 reads (14%) | called by muse, mutect2, varscan2
- OR7D1P | n.687C>A | RNA (SNP) | VAF 50/272 reads (18%) | called by muse, mutect2, varscan2
- PRMT3 | c.28+66G>C | Intron (SNP) | VAF 38/271 reads (14%) | called by muse, mutect2, varscan2
- PRMT3 | c.28+67G>T | Intron (SNP) | VAF 38/274 reads (14%) | called by muse, mutect2, varscan2
- PRSS1 | c.200+329A>C | Intron (SNP) | VAF 13/219 reads (6%) | called by muse, mutect2
- REG3G | c.*12A>G | 3'UTR (SNP) | VAF 13/124 reads (10%) | catalogued as COSV99709592; called by muse, mutect2, varscan2
- SNCA | c.306+14C>T | Intron (SNP) | VAF 43/327 reads (13%) | catalogued as rs964912778, COSV61136594; called by muse, mutect2, varscan2
- SPATA7 | c.*26G>T | 3'UTR (SNP) | VAF 13/214 reads (6%) | called by muse, mutect2
- SPRR2C | n.59T>A | RNA (SNP) | VAF 14/285 reads (5%) | called by muse, mutect2
- SYNE2 | c.788-714G>A | Intron (SNP) | VAF 33/223 reads (15%) | called by muse, mutect2, varscan2
- TJP1 | c.84+38C>G | Intron (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
